Somatic mutation profile of tumor specimen C3L-01951-01 (aliquot CPT0092680009) from CPTAC case C3L-01951, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 51.3 years (18,722 days).
Specimen C3L-01951-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9c17aad-3310-4a87-a9f3-1b1cee09ad49.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01951-31 (Blood Derived Normal), aliquot CPT0092080002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e4d595c-b119-4457-9357-a7751aaf3d62

The open-access MAF lists 79 somatic variants for this specimen: 49 protein-altering or splice-affecting, 13 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 13, Intron 11, Frame Shift Ins 5, Nonsense Mutation 4, Frame Shift Del 4, 5'UTR 3, Splice Site 2, 3'Flank 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX46 | c.449A>G p.N150S | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1255695568; called by muse, mutect2
- GRHL3 | c.1543+1G>T p.X515_splice (on ENST00000350501 / NM_198174.3; = p.X520_splice on NM_021180.3) | Splice Site (SNP) | VAF 20/93 reads (22%) | catalogued as COSV52563947; called by muse, mutect2, varscan2
- SECISBP2 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 106/408 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV104405134; called by muse, mutect2, varscan2
- SETD2 | c.4973C>T p.S1658L | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV57436224, COSV57446986; called by muse, mutect2, varscan2
- SLC44A2 | c.1963G>A p.G655S | Missense Mutation (SNP) | VAF 66/313 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.393); catalogued as rs1223992851; called by muse, mutect2, varscan2
- TSPAN10 | c.565C>T p.R189C (on ENST00000574882 / NM_001290212.1; = p.R151C on NM_031945.4) | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs781258302; called by muse, mutect2
- VHL | c.358A>T p.R120* | Nonsense Mutation (SNP) | VAF 131/295 reads (44%) | catalogued as CM014753, COSV56542964, COSV56545452; called by muse, mutect2, varscan2
- ACE | c.77C>G p.P26R | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- APPL1 | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 24/84 reads (29%) | called by muse, mutect2, varscan2
- ARID2 | c.1978dup p.S660Ffs*47 | Frame Shift Ins (INS) | VAF 57/235 reads (24%) | called by mutect2, pindel, varscan2
- CSPG4 | c.6633G>T p.K2211N | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP2D7 | c.875A>G p.D292G | Missense Mutation (SNP) | VAF 72/320 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- ECM2 | c.1821T>G p.Y607* | Nonsense Mutation (SNP) | VAF 81/343 reads (24%) | called by muse, mutect2, varscan2
- FAM186A | c.2893G>A p.G965R | Missense Mutation (SNP) | VAF 63/286 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- GUCD1 | c.112T>A p.S38T | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- HBP1 | c.620G>T p.W207L | Missense Mutation (SNP) | VAF 49/209 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- KIAA1549 | c.5408A>T p.E1803V | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- KIDINS220 | c.660dup p.E221Rfs*14 | Frame Shift Ins (INS) | VAF 54/255 reads (21%) | called by mutect2, pindel, varscan2
- KRT10 | c.251G>T p.S84I | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LBR | c.1837T>C p.Y613H | Missense Mutation (SNP) | VAF 98/350 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- LIG1 | c.1441del p.V481Wfs*21 | Frame Shift Del (DEL) | VAF 74/325 reads (23%) | called by mutect2, pindel, varscan2
- MYCBPAP | c.652G>T p.E218* | Nonsense Mutation (SNP) | VAF 11/62 reads (18%) | called by muse, mutect2, varscan2
- NOXO1 | c.215A>G p.K72R (on ENST00000397280 / NM_172168.3; = p.K71R on NM_144603.4) | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- OR1I1 | c.815del p.K272Rfs*5 | Frame Shift Del (DEL) | VAF 75/317 reads (24%) | called by mutect2, pindel, varscan2
- PAM | c.1996A>G p.I666V | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PBRM1 | c.1249_1250del p.Y417Pfs*2 | Frame Shift Del (DEL) | VAF 52/179 reads (29%) | called by mutect2, pindel, varscan2
- PGR | c.1880G>A p.C627Y | Missense Mutation (SNP) | VAF 75/240 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PSTPIP2 | c.805G>T p.V269L | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PTH2R | c.1013G>C p.R338T | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RASAL3 | c.2852A>G p.H951R | Missense Mutation (SNP) | VAF 47/199 reads (24%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- RASD2 | c.67G>T p.V23L | Missense Mutation (SNP) | VAF 65/302 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPS6KA5 | c.1158_1170del p.N387* | Frame Shift Del (DEL) | VAF 33/213 reads (15%) | called by mutect2, pindel, varscan2
- SLC23A3 | c.1793G>T p.C598F (on ENST00000409878 / NM_001144889.2; = p.C481F on NM_144712.5) | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- SLC30A6 | c.1267A>T p.M423L | Missense Mutation (SNP) | VAF 50/314 reads (16%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC7A14 | c.938A>T p.Y313F | Missense Mutation (SNP) | VAF 107/375 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- SMPD3 | c.1151A>T p.Y384F | Missense Mutation (SNP) | VAF 100/364 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- SMURF2 | c.1331T>A p.L444H | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SPATA13 | c.973-10_984del p.X325_splice | Splice Site (DEL) | VAF 34/126 reads (27%) | called by mutect2, pindel, varscan2
- STARD9 | c.26G>T p.R9L | Missense Mutation (SNP) | VAF 64/243 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STIM2 | c.803G>C p.R268T | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- THADA | c.1616T>C p.L539S | Missense Mutation (SNP) | VAF 51/238 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- TMEM214 | c.389G>C p.S130T | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- TSC1 | c.698dup p.L233Ffs*9 | Frame Shift Ins (INS) | VAF 141/568 reads (25%) | called by mutect2, pindel, varscan2
- TVP23C | c.204dup p.I69Yfs*7 | Frame Shift Ins (INS) | VAF 114/436 reads (26%) | called by mutect2, varscan2
- UBE2O | c.611T>A p.I204N | Missense Mutation (SNP) | VAF 63/255 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- WDFY3 | c.7519G>T p.D2507Y | Missense Mutation (SNP) | VAF 50/246 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- WNK4 | c.1706T>A p.F569Y | Missense Mutation (SNP) | VAF 133/418 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZFP36L2 | c.1349dup p.D451Gfs*23 | Frame Shift Ins (INS) | VAF 38/142 reads (27%) | called by mutect2, varscan2
- ZSWIM3 | c.475T>A p.S159T | Missense Mutation (SNP) | VAF 103/344 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CACNB2 | c.219G>A p.S73= (on ENST00000324631 / NM_201596.3; = p.S18= on NM_000724.4) | Silent (SNP) | VAF 104/386 reads (27%) | catalogued as rs779134360; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAI4 | c.1699C>A p.R567= | Silent (SNP) | VAF 59/224 reads (26%) | catalogued as COSV64021314; called by muse, mutect2, varscan2
- FSD1 | c.888G>A p.K296= | Silent (SNP) | VAF 67/226 reads (30%) | catalogued as rs938995624; called by muse, mutect2, varscan2
- GPLD1 | c.2044C>T p.L682= | Silent (SNP) | VAF 35/134 reads (26%) | called by muse, mutect2, varscan2
- IL22RA1 | c.843C>T p.H281= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs138064122; called by muse, mutect2, varscan2
- OR4A47 | c.381C>T p.P127= | Silent (SNP) | VAF 63/234 reads (27%) | catalogued as rs776153456; called by muse, mutect2, varscan2
- OR4K5 | c.324T>A p.T108= | Silent (SNP) | VAF 107/379 reads (28%) | called by muse, mutect2, varscan2
- PCSK1 | c.642A>G p.G214= | Silent (SNP) | VAF 100/406 reads (25%) | called by muse, mutect2, varscan2
- PGR | c.1881C>T p.C627= | Silent (SNP) | VAF 74/241 reads (31%) | catalogued as COSV54795864; called by muse, mutect2, varscan2
- PPP4R3B | c.666C>T p.V222= | Silent (SNP) | VAF 110/391 reads (28%) | catalogued as rs754222273, COSV55402928; called by muse, mutect2, varscan2
- PXDNL | c.795T>A p.I265= | Silent (SNP) | VAF 40/121 reads (33%) | called by muse, mutect2, varscan2
- SDR9C7 | c.267G>A p.A89= | Silent (SNP) | VAF 34/149 reads (23%) | catalogued as rs541025681, COSV53290878; called by muse, mutect2
- SETD9 | c.621T>C p.P207= | Silent (SNP) | VAF 42/158 reads (27%) | catalogued as rs1213115574; called by muse, mutect2, varscan2
- ACOT11 | c.1629+937A>G | Intron (SNP) | VAF 65/246 reads (26%) | called by muse, mutect2, varscan2
- ADAMTS1 | c.730+460G>C | Intron (SNP) | VAF 18/174 reads (10%) | catalogued as rs761925336; called by muse, mutect2
- ARID2 | chr12:45727572 C>T | 5'Flank (SNP) | VAF 26/96 reads (27%) | catalogued as rs1293000132; called by muse, mutect2, varscan2
- ARID4B | c.-2T>C | 5'UTR (SNP) | VAF 42/201 reads (21%) | called by muse, mutect2, varscan2
- C17orf49 | chr17:7017624 G>A | 3'Flank (SNP) | VAF 60/197 reads (30%) | catalogued as rs1045712676; called by muse, mutect2, varscan2
- CLK4 | c.162-1888G>A | Intron (SNP) | VAF 31/100 reads (31%) | catalogued as COSV60318346; called by muse, mutect2, varscan2
- EBF2 | c.1528+228C>T | Intron (SNP) | VAF 25/134 reads (19%) | catalogued as rs748660361; called by muse, mutect2, varscan2
- EIF2AK1 | c.1764+228G>A | Intron (SNP) | VAF 49/216 reads (23%) | catalogued as rs1244815900; called by muse, mutect2, varscan2
- MTHFD1 | c.2280-27C>A | Intron (SNP) | VAF 91/329 reads (28%) | called by muse, mutect2, varscan2
- NR5A2 | c.65-918C>A | Intron (SNP) | VAF 66/196 reads (34%) | called by muse, mutect2, varscan2
- OLFM1 | c.-54del | 5'UTR (DEL) | VAF 27/105 reads (26%) | called by mutect2, pindel, varscan2
- RAB40C | chr16:630261 C>A | 3'Flank (SNP) | VAF 32/159 reads (20%) | catalogued as rs1253941952; called by muse, mutect2, varscan2
- SGSM2 | c.1653+89G>C | Intron (SNP) | VAF 25/128 reads (20%) | called by muse, mutect2, varscan2
- SPATA21 | c.145-800C>T | Intron (SNP) | VAF 19/56 reads (34%) | called by muse, mutect2, varscan2
- STARD3 | c.429+72T>A | Intron (SNP) | VAF 18/106 reads (17%) | catalogued as rs1411606208; called by muse, mutect2, varscan2
- STK24 | c.1295+619_1295+624delinsA | Intron (DEL) | VAF 30/168 reads (18%) | called by pindel, varscan2*
- UPF3B | c.-26A>C | 5'UTR (SNP) | VAF 60/136 reads (44%) | called by muse, mutect2, varscan2
